Somatic mutation profile of cancer-model specimen HCM-CSHL-0085-C24-85A (3D Organoid; aliquot HCM-CSHL-0085-C24-85A-01D-A78L-36), derived from the primary tumor of HCMI case HCM-CSHL-0085-C24, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Ampulla of Vater; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 56.0 years (20,466 days).
Specimen HCM-CSHL-0085-C24-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e8e4c9c9-af8c-4fa3-ac79-6f0afd063077.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0085-C24-10A (Blood Derived Normal), aliquot HCM-CSHL-0085-C24-10A-01D-A78L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/741a19e2-0add-475f-980e-25852200db0b

The open-access MAF lists 130 somatic variants for this specimen: 88 protein-altering or splice-affecting, 31 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 74, Silent 31, RNA 4, Intron 3, Nonsense Mutation 3, Splice Region 3, 5'UTR 2, Translation Start Site 2, Frame Shift Del 2, Splice Site 2, Frame Shift Ins 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.121A>G p.T41A | Missense Mutation (SNP) | VAF 147/304 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as rs121913412, COSV62687862, COSV62689580, COSV62714770; ClinVar: conflicting interpretations of pathogenicity / pathogenic /  other / likely pathogenic; called by muse, mutect2, varscan2
- AC013489.1 | c.568G>A p.D190N | Missense Mutation (SNP) | VAF 44/87 reads (51%) | SIFT tolerated (0.19); PolyPhen benign (0.259); catalogued as COSV51552966; called by muse, mutect2, varscan2
- ADGRB1 | c.2202G>A p.A734= | Splice Region (SNP) | VAF 106/157 reads (68%) | catalogued as rs753558928; called by muse, mutect2, varscan2
- ADGRB1 | c.4604G>A p.R1535Q | Missense Mutation (SNP) | VAF 232/387 reads (60%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.988); catalogued as COSV60097426; called by muse, mutect2, varscan2
- ANK2 | c.2365G>A p.A789T | Missense Mutation (SNP) | VAF 241/488 reads (49%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.596); catalogued as rs1238418730; called by muse, mutect2, varscan2
- ARID2 | c.1352del p.S451Lfs*12 | Frame Shift Del (DEL) | VAF 85/116 reads (73%) | catalogued as COSV57600163; called by mutect2, pindel, varscan2
- ATP9A | c.1655G>T p.G552V | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1256304115; called by muse, mutect2, varscan2
- C11orf87 | c.371C>A p.T124N | Missense Mutation (SNP) | VAF 85/294 reads (29%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as COSV59357231; called by muse, mutect2, varscan2
- CALHM2 | c.824G>A p.R275Q | Missense Mutation (SNP) | VAF 105/199 reads (53%) | SIFT tolerated (0.25); PolyPhen benign (0.322); catalogued as rs377104588; called by muse, mutect2, varscan2
- CLTCL1 | c.541A>G p.M181V | Missense Mutation (SNP) | VAF 75/242 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.666); catalogued as rs1555966213; called by muse, mutect2, varscan2
- CSN1S1 | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.311); catalogued as rs372612450, COSV55891851; called by muse, mutect2, varscan2
- DACT3 | c.617C>T p.A206V | Missense Mutation (SNP) | VAF 74/122 reads (61%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.564); catalogued as rs1267678211; called by muse, mutect2, varscan2
- EPHA1 | c.2671C>T p.R891W | Missense Mutation (SNP) | VAF 68/119 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs767930814; called by muse, mutect2, varscan2
- ESPNL | c.2083C>T p.R695C | Missense Mutation (SNP) | VAF 87/300 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs927691376; called by muse, mutect2, varscan2
- FCGRT | c.877C>G p.P293A | Missense Mutation (SNP) | VAF 83/215 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.137); catalogued as COSV54543655; called by muse, mutect2, varscan2
- FERD3L | c.97T>G p.F33V | Missense Mutation (SNP) | VAF 72/216 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as COSV51761712; called by muse, mutect2, varscan2
- FSTL5 | c.1507_1508dup p.W503Cfs*37 | Frame Shift Ins (INS) | VAF 47/104 reads (45%) | catalogued as COSV60196626; called by mutect2, varscan2
- GLI3 | c.3116C>T p.A1039V | Missense Mutation (SNP) | VAF 98/324 reads (30%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV67890781, COSV99060470; called by muse, mutect2, varscan2
- GTSE1 | c.349C>T p.R117W | Missense Mutation (SNP) | VAF 80/363 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs556488388; called by muse, mutect2, varscan2
- HCAR2 | c.985G>A p.V329I | Missense Mutation (SNP) | VAF 24/318 reads (8%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs200174813, COSV61024981; called by muse, mutect2
- HCAR3 | c.985G>A p.V329I | Missense Mutation (SNP) | VAF 91/179 reads (51%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs368546949; called by muse, mutect2, varscan2
- HOGA1 | c.284G>A p.R95H | Missense Mutation (SNP) | VAF 147/308 reads (48%) | SIFT tolerated (0.56); PolyPhen benign (0.023); catalogued as rs754634699, COSV65706481; called by muse, mutect2, varscan2
- ICAM5 | c.588C>A p.F196L | Missense Mutation (SNP) | VAF 214/446 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV55748939; called by muse, mutect2, varscan2
- KLHL1 | c.1769G>A p.R590Q | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748882149, COSV64769060, COSV64786398; called by muse, mutect2, varscan2
- LRRTM4 | c.961C>T p.P321S | Missense Mutation (SNP) | VAF 139/139 reads (100%) | SIFT tolerated (0.41); PolyPhen benign (0.259); catalogued as COSV69142997; called by muse, mutect2, varscan2
- MCRIP1 | c.28G>A p.V10M | Missense Mutation (SNP) | VAF 51/132 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs754717613; called by muse, mutect2, varscan2
- NBEA | c.2118A>G p.I706M | Missense Mutation (SNP) | VAF 7/116 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1365413222; called by muse, mutect2
- NCR2 | c.430G>A p.D144N | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs757739549, COSV66100651; called by muse, mutect2
- OR2J2 | c.125G>A p.G42E | Missense Mutation (SNP) | VAF 43/117 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs755187820; called by muse, mutect2, varscan2
- OR4A16 | c.260A>C p.K87T | Missense Mutation (SNP) | VAF 201/201 reads (100%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.066); catalogued as COSV59042819; called by muse, mutect2, varscan2
- OR52K1 | c.777C>G p.I259M | Missense Mutation (SNP) | VAF 142/281 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV56903654, COSV56904063; called by muse, mutect2, varscan2
- P2RY14 | c.937C>A p.P313T | Missense Mutation (SNP) | VAF 44/213 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0.005); catalogued as COSV56391075; called by muse, mutect2, varscan2
- PARP10 | c.2545C>T p.R849C | Missense Mutation (SNP) | VAF 189/263 reads (72%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs782649313, COSV57299228; called by muse, mutect2, varscan2
- PCDHB15 | c.1246G>A p.E416K | Missense Mutation (SNP) | VAF 100/218 reads (46%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.612); catalogued as rs1554292027; called by muse, mutect2, varscan2
- PLEKHM3 | c.1309C>T p.R437* | Nonsense Mutation (SNP) | VAF 191/191 reads (100%) | catalogued as rs1447181721; called by muse, mutect2, varscan2
- PLXND1 | c.2627G>A p.R876H | Missense Mutation (SNP) | VAF 102/446 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.92); catalogued as rs554042254; called by muse, mutect2, varscan2
- PRR23A | c.779G>A p.R260H | Missense Mutation (SNP) | VAF 71/96 reads (74%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as COSV67214028; called by muse, mutect2, varscan2
- RAD50 | c.1892A>C p.D631A | Missense Mutation (SNP) | VAF 111/267 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as rs1372866109; called by muse, mutect2, varscan2
- RHBDF2 | c.1080T>G p.F360L | Missense Mutation (SNP) | VAF 120/588 reads (20%) | SIFT tolerated (0.83); PolyPhen benign (0.009); catalogued as rs548469800; called by muse, mutect2, varscan2
- RYR3 | c.13120C>T p.R4374W (on ENST00000389232; = p.R4375W on NM_001036.6) | Missense Mutation (SNP) | VAF 101/259 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs759909362, COSV66778249; called by muse, mutect2, varscan2
- SIRPB1 | c.432C>T p.R144= | Splice Region (SNP) | VAF 124/529 reads (23%) | catalogued as rs200840558, COSV53537445; called by muse, mutect2, varscan2
- SLC24A3 | c.874G>A p.D292N | Missense Mutation (SNP) | VAF 79/435 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.052); catalogued as rs765357990; called by muse, mutect2, varscan2
- SRD5A1 | c.556C>T p.P186S | Missense Mutation (SNP) | VAF 119/119 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57014835; called by muse, mutect2, varscan2
- TDRD9 | c.4082G>A p.R1361H | Missense Mutation (SNP) | VAF 77/167 reads (46%) | SIFT tolerated (0.42); PolyPhen benign (0.132); catalogued as rs142470189; called by muse, mutect2, varscan2
- TPTE2 | c.452C>G p.P151R | Missense Mutation (SNP) | VAF 90/108 reads (83%) | SIFT deleterious (0.01); PolyPhen benign (0.143); catalogued as COSV55023847; called by muse, mutect2, varscan2
- TRDN | c.278G>A p.R93H | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1371219098, COSV100522147; called by muse, mutect2, varscan2
- TTN | c.31129G>A p.A10377T (on ENST00000591111; = p.A9450T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 103/104 reads (99%) | PolyPhen benign (0.025); catalogued as rs756672871; called by muse, mutect2, varscan2
- UNC5C | c.2225G>A p.R742H | Missense Mutation (SNP) | VAF 47/129 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs142722408; called by muse, mutect2, varscan2
- ZSCAN9 | c.987G>C p.Q329H | Missense Mutation (SNP) | VAF 86/163 reads (53%) | SIFT tolerated (0.13); PolyPhen benign (0.378); catalogued as COSV99356463; called by muse, mutect2, varscan2
- ACO1 | c.241G>A p.A81T | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.648); called by muse, mutect2, varscan2
- ADAM9 | c.333+2T>A p.X111_splice | Splice Site (SNP) | VAF 57/226 reads (25%) | called by muse, mutect2, varscan2
- ANK2 | c.2694-4C>T | Splice Region (SNP) | VAF 152/291 reads (52%) | called by muse, mutect2, varscan2
- ANK3 | c.11560A>G p.K3854E | Missense Mutation (SNP) | VAF 98/333 reads (29%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AP5M1 | c.593G>A p.W198* | Nonsense Mutation (SNP) | VAF 209/210 reads (100%) | called by muse, mutect2, varscan2
- ASCL3 | c.17G>T p.G6V | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- CCDC141 | c.1684C>A p.Q562K | Missense Mutation (SNP) | VAF 112/112 reads (100%) | SIFT tolerated (0.32); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CDH12 | c.1967A>C p.N656T | Missense Mutation (SNP) | VAF 108/193 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CIB1 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- DCLK1 | c.1944+2T>G p.X648_splice | Splice Site (SNP) | VAF 9/76 reads (12%) | called by muse, mutect2, varscan2
- DDX10 | c.1884G>T p.E628D | Missense Mutation (SNP) | VAF 14/304 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ESF1 | c.1712G>C p.S571T | Missense Mutation (SNP) | VAF 116/116 reads (100%) | SIFT tolerated (0.18); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- GPR75 | c.740C>A p.S247Y | Missense Mutation (SNP) | VAF 274/275 reads (100%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- HMCN2 | c.12859G>C p.E4287Q | Missense Mutation (SNP) | VAF 89/195 reads (46%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- IPO7 | c.868G>A p.E290K | Missense Mutation (SNP) | VAF 62/63 reads (98%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- LRRC66 | c.624C>G p.F208L | Missense Mutation (SNP) | VAF 61/127 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- LRRTM4 | c.735C>A p.S245R | Missense Mutation (SNP) | VAF 56/206 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- MAL2 | c.416C>G p.P139R | Missense Mutation (SNP) | VAF 106/413 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.58); called by muse, mutect2, varscan2
- NAAA | c.578del p.G193Vfs*27 | Frame Shift Del (DEL) | VAF 36/67 reads (54%) | called by mutect2, pindel, varscan2
- NRDC | c.2434G>C p.D812H | Missense Mutation (SNP) | VAF 65/65 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- PHKG1 | c.537G>C p.E179D | Missense Mutation (SNP) | VAF 57/143 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- PIP5K1C | c.1819G>A p.A607T | Missense Mutation (SNP) | VAF 240/526 reads (46%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLK2 | c.1051G>C p.V351L | Missense Mutation (SNP) | VAF 63/63 reads (100%) | SIFT tolerated (0.13); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- PPP1R3A | c.2363G>T p.C788F | Missense Mutation (SNP) | VAF 48/166 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PRKDC | c.1068_1070del p.N356del | In Frame Del (DEL) | VAF 60/126 reads (48%) | called by pindel, varscan2
- PRR16 | c.397A>T p.K133* (on ENST00000407149 / NM_001300783.2; = p.K110* on NM_016644.2) | Nonsense Mutation (SNP) | VAF 40/91 reads (44%) | called by muse, mutect2, varscan2
- PTGER3 | c.463C>T p.R155W | Missense Mutation (SNP) | VAF 88/183 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RGS20 | c.559G>A p.A187T (on ENST00000297313 / NM_170587.4; = p.A40T on NM_003702.4) | Missense Mutation (SNP) | VAF 58/173 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.041); called by muse, varscan2
- RNF6 | c.349T>C p.F117L | Missense Mutation (SNP) | VAF 112/259 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- RYR3 | c.6783A>C p.Q2261H | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SEMA3A | c.1003T>G p.F335V | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SF3A3 | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 161/162 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- SLC6A4 | c.1387G>C p.E463Q | Missense Mutation (SNP) | VAF 120/120 reads (100%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SPINK5 | c.1402A>C p.N468H | Missense Mutation (SNP) | VAF 223/456 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TTN | c.56612A>C p.K18871T (on ENST00000591111; = p.K11447T on NM_003319.4) | Missense Mutation (SNP) | VAF 36/36 reads (100%) | PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- XYLT2 | c.456G>C p.Q152H | Missense Mutation (SNP) | VAF 375/375 reads (100%) | SIFT tolerated (0.06); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ZDHHC6 | c.404G>A p.C135Y | Missense Mutation (SNP) | VAF 108/152 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF385D | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 27/105 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZSCAN29 | c.380C>T p.S127L | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- ADAMTS16 | c.1287C>T p.F429= | Silent (SNP) | VAF 63/130 reads (48%) | called by muse, mutect2, varscan2
- AKIRIN1 | c.393A>G p.T131= | Silent (SNP) | VAF 40/71 reads (56%) | catalogued as rs1298893257; called by muse, mutect2, varscan2
- ALPK2 | c.3045C>T p.T1015= | Silent (SNP) | VAF 46/111 reads (41%) | catalogued as rs541753586; called by muse, mutect2, varscan2
- ANKRD1 | c.657C>A p.L219= | Silent (SNP) | VAF 232/511 reads (45%) | catalogued as COSV100865362; called by muse, mutect2, varscan2
- ARPP21 | c.1317A>G p.A439= | Silent (SNP) | VAF 125/291 reads (43%) | catalogued as COSV51806064; called by muse, mutect2, varscan2
- ASCL3 | c.18C>T p.G6= | Silent (SNP) | VAF 23/49 reads (47%) | catalogued as COSV100366920; called by muse, mutect2, varscan2
- C3AR1 | c.183C>T p.F61= | Silent (SNP) | VAF 98/184 reads (53%) | called by muse, mutect2, varscan2
- CCDC160 | c.582G>A p.T194= | Silent (SNP) | VAF 145/145 reads (100%) | catalogued as rs751796060, COSV66251327; called by muse, mutect2, varscan2
- CLCA1 | c.1791G>A p.T597= | Silent (SNP) | VAF 203/409 reads (50%) | catalogued as rs899149911, COSV52327435; called by muse, mutect2, varscan2
- DDX3X | c.228T>C p.D76= (on ENST00000399959; = p.D77= on NM_001356.5) | Silent (SNP) | VAF 82/82 reads (100%) | called by muse, mutect2, varscan2
- DEPDC5 | c.2256G>T p.L752= (on ENST00000400246; = p.L821= on NM_014662.5) | Silent (SNP) | VAF 95/133 reads (71%) | called by muse, mutect2, varscan2
- FAM209A | c.447G>A p.K149= | Silent (SNP) | VAF 164/164 reads (100%) | called by muse, mutect2, varscan2
- FAT4 | c.10095A>C p.R3365= | Silent (SNP) | VAF 82/175 reads (47%) | called by muse, mutect2, varscan2
- FGL1 | c.927A>G p.P309= | Silent (SNP) | VAF 34/96 reads (35%) | called by mutect2, varscan2
- GRIN1 | c.114C>T p.H38= | Silent (SNP) | VAF 186/378 reads (49%) | catalogued as rs1241572680, COSV59300354; called by muse, mutect2, varscan2
- HDAC7 | c.1980T>C p.G660= (on ENST00000427332; = p.G699= on NM_015401.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 103/104 reads (99%) | called by muse, mutect2, varscan2
- IGLV3-1 | c.228C>T p.I76= | Silent (SNP) | VAF 227/824 reads (28%) | catalogued as rs368264920; called by muse, mutect2, varscan2
- IL4 | c.147C>T p.T49= | Silent (SNP) | VAF 45/93 reads (48%) | catalogued as rs759103191; called by muse, mutect2, varscan2
- KRT5 | c.75G>A p.P25= | Silent (SNP) | VAF 86/160 reads (54%) | catalogued as rs572849401; called by muse, mutect2, varscan2
- LAMA5 | c.2058C>T p.H686= | Silent (SNP) | VAF 62/254 reads (24%) | catalogued as rs779668173; called by muse, mutect2, varscan2
- MDGA2 | c.372A>T p.G124= | Silent (SNP) | VAF 140/141 reads (99%) | called by muse, mutect2, varscan2
- MRPL39 | c.459G>T p.V153= | Silent (SNP) | VAF 62/153 reads (41%) | catalogued as COSV56262340; called by muse, mutect2, varscan2
- OR56B4 | c.810G>A p.E270= | Silent (SNP) | VAF 357/357 reads (100%) | called by muse, mutect2, varscan2
- PAXIP1 | c.2868C>T p.F956= | Silent (SNP) | VAF 65/255 reads (25%) | called by muse, mutect2, varscan2
- PROM1 | c.2094C>T p.S698= | Silent (SNP) | VAF 49/107 reads (46%) | catalogued as rs199727800, CM1312881; called by muse, mutect2, varscan2
- RINL | c.786C>T p.H262= (on ENST00000591812 / NM_001195833.2; = p.H148= on NM_198445.4) | Silent (SNP) | VAF 169/366 reads (46%) | catalogued as rs779162874; called by muse, mutect2, varscan2
- SYDE1 | c.819C>T p.Y273= | Silent (SNP) | VAF 53/112 reads (47%) | catalogued as rs1413962871; called by muse, mutect2, varscan2
- TFEB | c.37C>A p.R13= | Silent (SNP) | VAF 67/129 reads (52%) | catalogued as COSV57824244; called by muse, mutect2, varscan2
- TLE4 | c.837A>T p.L279= | Silent (SNP) | VAF 55/181 reads (30%) | called by muse, mutect2, varscan2
- TRPM8 | c.2286G>A p.S762= | Silent (SNP) | VAF 769/769 reads (100%) | catalogued as rs199933698, COSV61222637; called by muse, mutect2, varscan2
- ZWILCH | c.1020C>T p.F340= | Silent (SNP) | VAF 62/156 reads (40%) | catalogued as rs769354705; called by muse, mutect2, varscan2
- CREB5 | chr7:28409791 G>A | 5'Flank (SNP) | VAF 46/114 reads (40%) | catalogued as rs1461952039; called by muse, mutect2
- CYHR1 | c.-29T>C | 5'UTR (SNP) | VAF 125/403 reads (31%) | called by muse, mutect2, varscan2
- EP300 | c.*2G>C | 3'UTR (SNP) | VAF 38/142 reads (27%) | catalogued as COSV54326918; called by muse, mutect2, varscan2
- FOXP2 | c.168+36459C>T | Intron (SNP) | VAF 31/76 reads (41%) | called by muse, mutect2, varscan2
- GALNT13 | c.1531-3742T>C | Intron (SNP) | VAF 63/205 reads (31%) | called by muse, mutect2, varscan2
- LEPR | c.-120C>G | 5'UTR (SNP) | VAF 359/360 reads (100%) | called by muse, mutect2, varscan2
- OR4N3P | n.687T>G | RNA (SNP) | VAF 29/133 reads (22%) | called by muse, mutect2, varscan2
- PARGP1 | n.1966C>T | RNA (SNP) | VAF 53/253 reads (21%) | catalogued as rs1374034744; called by muse, mutect2, varscan2
- RBPJ | c.194+3803C>G | Intron (SNP) | VAF 14/41 reads (34%) | called by muse, mutect2, varscan2
- SNORD116-3 | n.74G>A | RNA (SNP) | VAF 122/326 reads (37%) | catalogued as rs568283973; called by muse, mutect2, varscan2
- UBTFL2 | n.483A>G | RNA (SNP) | VAF 589/600 reads (98%) | catalogued as rs1433232626; called by muse, mutect2, varscan2
